Somatic mutation profile of tumor specimen TCGA-AC-A5XU-01A (aliquot TCGA-AC-A5XU-01A-11D-A28B-09) from TCGA case TCGA-AC-A5XU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.4 years (27,191 days).
Specimen TCGA-AC-A5XU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce09de27-a89e-4b64-ba7c-5d9c21667a61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A5XU-10A (Blood Derived Normal), aliquot TCGA-AC-A5XU-10A-01D-A28E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17a68991-4bd5-42c4-a7ad-6fd1a2536a1b

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 18, Nonsense Mutation 4, In Frame Del 1, Intron 1, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 5/10 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs375338359, CM098494, COSV52690857, COSV52980226, COSV53438718; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.74G>C p.C25S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99221893; called by muse, mutect2, varscan2
- ADAMTS9 | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.94); PolyPhen benign (0.044); catalogued as rs775861579, COSV55781203; called by muse, mutect2, varscan2
- BOD1L1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50015843, COSV99240474; called by muse, mutect2
- CCDC136 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV99923188; called by muse, mutect2, varscan2
- CCDC68 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV61603533; called by muse, mutect2, varscan2
- CSF2RB | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV99454448; called by muse, mutect2, varscan2
- DPP6 | c.2122G>A p.V708M (on ENST00000377770 / NM_001364500.2; = p.V646M on NM_001936.5) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746793201, COSV100128050; called by muse, mutect2
- EEPD1 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99633057; called by muse, mutect2, varscan2
- EFCAB5 | c.2474C>T p.T825I | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100300745; called by muse, mutect2, varscan2
- EPB41L2 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs140419333; called by muse, mutect2, varscan2
- FOXB2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as COSV100942392; called by muse, mutect2
- HAVCR1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs777468511, COSV59404553; called by muse, varscan2
- MASP2 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101280431; called by muse, mutect2, varscan2
- MCM7 | c.365C>G p.P122R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100385162; called by muse, mutect2, varscan2
- MEGF8 | c.7159G>A p.D2387N (on ENST00000251268 / NM_001271938.2; = p.D2320N on NM_001410.3) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.989); catalogued as COSV99239006; called by muse, mutect2, varscan2
- MMP14 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774971754, COSV100314321; called by muse, mutect2, varscan2
- MTREX | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV100044520; called by muse, mutect2
- MYBL2 | c.1418T>A p.L473Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935627847, COSV99406741; called by muse, mutect2, varscan2
- NTM | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs951593215, COSV66177489; called by muse, mutect2, varscan2
- OLFML2A | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs199680116; called by muse, mutect2, varscan2
- OMD | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.436); catalogued as COSV100979087; called by muse, mutect2, varscan2
- OTOGL | c.6532C>T p.P2178S (on ENST00000547103; = p.P2169S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100087911; called by muse, mutect2, varscan2
- OVCH1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs755948877, COSV58967968; called by muse, mutect2, varscan2
- PAPSS2 | c.1336G>A p.G446S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373228712; called by muse, mutect2, varscan2
- PARP4 | c.2581C>G p.Q861E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs753015710, COSV101132050; called by muse, mutect2, varscan2
- PLSCR4 | c.958T>G p.F320V | Missense Mutation (SNP) | VAF 76/86 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100724356; called by muse, mutect2, varscan2
- SIPA1 | c.2644C>A p.P882T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs747257834, COSV100425942; called by muse, mutect2, varscan2
- SLC16A6 | c.710C>T p.S237F | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59178954; called by muse, mutect2
- SUZ12 | c.907G>C p.D303H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100497092; called by muse, mutect2, varscan2
- SYT9 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs147763195; called by mutect2, varscan2
- TAGAP | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs764365414, COSV100487648; called by muse, mutect2, varscan2
- TIMM44 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99564346; called by muse, mutect2, varscan2
- TUBB1 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); catalogued as COSV99414249; called by muse, mutect2, varscan2
- USP15 | c.1552G>A p.D518N (on ENST00000280377 / NM_001351159.2; = p.D489N on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV99740625; called by muse, mutect2
- WFS1 | c.2581G>A p.V861M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs752775825, COSV99901601; called by muse, mutect2, varscan2
- ZNF417 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 16/221 reads (7%) | catalogued as COSV100364414; called by muse, mutect2
- ZNF441 | c.970C>T p.R324* | Nonsense Mutation (SNP) | VAF 19/36 reads (53%) | catalogued as rs140016466; called by muse, mutect2, varscan2
- ZNF565 | c.626G>A p.C209Y (on ENST00000355114; = p.C169Y on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV100412001; called by muse, mutect2, varscan2
- ZNF623 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.365); catalogued as COSV101513613; called by muse, mutect2, varscan2
- EMC9 | c.198+2_198+13del p.X66_splice | Splice Site (DEL) | VAF 19/36 reads (53%) | called by mutect2, pindel, varscan2
- HMGA1 | c.58_60del p.G20del | In Frame Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- IFIT2 | c.293dup p.N99Kfs*27 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- MED12 | c.4031_4033dup p.I1344dup | In Frame Ins (INS) | VAF 18/59 reads (31%) | called by mutect2, pindel, varscan2
- CACNA1E | c.6489G>A p.P2163= (on ENST00000367573 / NM_001205293.3; = p.P2120= on NM_000721.4) | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs377180948, COSV62388209; called by muse, mutect2, varscan2
- CACNB3 | c.759G>A p.E253= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99975114; called by muse, mutect2, varscan2
- CARS1 | c.288G>T p.T96= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99543520; called by muse, mutect2, varscan2
- CPED1 | c.168C>A p.T56= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100121477; called by mutect2, varscan2
- DLGAP2 | c.1839G>A p.T613= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs578172793, COSV101422690; called by muse, mutect2
- FRMPD4 | c.381G>A p.P127= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs753530543, COSV101042682, COSV101042878; called by muse, mutect2, varscan2
- GABBR1 | c.1050C>T p.P350= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs762967521, COSV63543923; called by muse, mutect2, varscan2
- GPR141 | c.63C>A p.I21= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100550424; called by muse, mutect2
- GPR75 | c.333T>C p.S111= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100766419; called by muse, mutect2, varscan2
- H1-4 | c.285G>A p.Q95= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99175388; called by muse, mutect2, varscan2
- MECP2 | c.474G>A p.T158= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs61748413, COSV100318501; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- PCDHA5 | c.1668C>T p.D556= | Silent (SNP) | VAF 38/129 reads (29%) | catalogued as rs1554129352, COSV65348905; called by muse, mutect2, varscan2
- SEPTIN12 | c.387C>T p.I129= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV51617681; called by muse, mutect2, varscan2
- TBC1D2B | c.2265A>T p.L755= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100317747; called by muse, mutect2, varscan2
- THUMPD3 | c.132A>G p.V44= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV100560767; called by muse, mutect2, varscan2
- TREX2 | c.135C>T p.S45= (on ENST00000334497; = p.S2= on NM_080701.3) | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1409751838, COSV100444306; called by muse, mutect2, varscan2
- WDR4 | c.1179G>A p.P393= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs759460966, COSV100375438, COSV57734516; called by muse, mutect2, varscan2
- ZNF648 | c.390C>T p.L130= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100374799; called by muse, mutect2, varscan2
- DNAH8 | c.-41-4547C>T | Intron (SNP) | VAF 5/46 reads (11%) | catalogued as rs368460226, COSV59492992; called by muse, mutect2
